Surgical pathology report (de-identified scan), TCGA case TCGA-ZB-A961, project TCGA-THYM (Thymoma), tissue source site Thoraxklinik, specimen TCGA-ZB-A961-01A (Primary Tumor).

Name:

Identifier:

Unique Patient #:

Tumor Type : Thymoma

ICD-O-3

Thymoma, type A, malignant

8581/3

Site: Thymus C38.1

QW4/7/14

Pathology Report-Summary:

Material:

Tumor: 4.0 x 3.6 x 1.5 cm

focal infiltration of capsule, and fat tissue

Diagnosis:

Type A-Thymoma

pT2, pNx (0/5)

Masaoka: II.2

Immunohistochemistry

epithelial cells positive for: CK5/6, KL1

epithelial cells negative for: CD1a, CD5, CD117, CD99, CD56, NSE, synaptophysin, TTF1, CD56, chromograninA

some CD1a-, CD5-positive immature T-lymphocytes

Source: NCI Genomic Data Commons file d7fbccbd-023a-4b67-8b2a-1e4272318a7a (TCGA-ZB-A961.E8BBC5EB-22F5-42FF-AE8D-85D89821FC00.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).